Somatic mutation profile of tumor specimen ALCH-AE2N-TTP1-A (aliquot ALCH-AE2N-TTP1-A-2-0-D-A604-36) from ALCHEMIST case ALCH-AE2N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,266 days).
Specimen ALCH-AE2N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aa68f96-bc48-4387-bfa5-9ea4453c94ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE2N-NB1-A (Blood Derived Normal), aliquot ALCH-AE2N-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/588702ef-c0cb-4986-9d05-1b3f4fcebdf7

The open-access MAF lists 125 somatic variants for this specimen: 88 protein-altering or splice-affecting, 22 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 22, Intron 6, Splice Site 5, Nonsense Mutation 5, RNA 4, 3'UTR 3, Frame Shift Del 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 172/860 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- A2M | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV59388445; called by muse, mutect2, varscan2
- ANKEF1 | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as rs553883114; called by muse, mutect2, varscan2
- ANKK1 | c.1710G>T p.R570S | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV58272501; called by muse, mutect2, varscan2
- ANKRD52 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57282053; called by muse, mutect2, varscan2
- BPIFC | c.1045A>G p.I349V | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1441384890; called by muse, mutect2, varscan2
- C1orf198 | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.291); catalogued as COSV64176378; called by muse, mutect2, varscan2
- C9orf43 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.038); catalogued as COSV55913406; called by muse, mutect2, varscan2
- COL11A1 | c.2044G>T p.G682C | Missense Mutation (SNP) | VAF 128/658 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62185616; called by muse, mutect2, varscan2
- CPO | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); catalogued as rs1295913643; called by muse, mutect2
- DGKB | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51772228; called by muse, varscan2
- DYRK2 | c.494A>G p.Q165R (on ENST00000344096 / NM_006482.3; = p.Q92R on NM_003583.4) | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV59846372; called by muse, mutect2, varscan2
- EGFR | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs483352806, CM132767, COSV51780730; ClinVar: not provided / drug response; called by muse, mutect2, varscan2
- EML4 | c.1799C>T p.T600I | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1170220534; called by muse, mutect2
- FAM47A | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.73); catalogued as COSV100650121, COSV60493685, COSV60499619; called by muse, mutect2, varscan2
- FAM83A | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1040748674; called by muse, mutect2, varscan2
- FAT1 | c.8266_8269del p.Q2756Afs*4 | Frame Shift Del (DEL) | VAF 42/322 reads (13%) | catalogued as rs1199646858; called by pindel, varscan2
- FREM3 | c.3320G>C p.C1107S | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61682233; called by muse, mutect2, varscan2
- GALNT13 | c.903C>A p.Y301* | Nonsense Mutation (SNP) | VAF 35/176 reads (20%) | catalogued as COSV101224373; called by muse, mutect2, varscan2
- GDPD3 | c.819+1G>A p.X273_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as rs150037677; called by muse, mutect2
- HUWE1 | c.12031G>T p.G4011W | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53348438; called by muse, mutect2, varscan2
- KLLN | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 116/634 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs962216778, COSV64288439; called by muse, mutect2, varscan2
- KRTAP13-4 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 101/468 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1220423192, COSV61880743; called by muse, mutect2, varscan2
- KRTAP4-2 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1179821766; called by muse, mutect2, varscan2
- MZF1 | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV53041285; called by muse, mutect2, varscan2
- NUP37 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 81/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51836942, COSV51839384; called by muse, mutect2, varscan2
- P2RY10 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV50680337; called by muse, mutect2, varscan2
- PANK2 | c.1352G>A p.R451Q (on ENST00000316562 / NM_153638.3; = p.R160Q on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/384 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.733); catalogued as COSV57254677; called by muse, mutect2, varscan2
- PKHD1 | c.9535C>T p.L3179F | Missense Mutation (SNP) | VAF 147/797 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs897671588, COSV100583205; called by muse, mutect2, varscan2
- PXDNL | c.2482G>T p.D828Y | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62498058; called by muse, mutect2, varscan2
- SHOX | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1443010174, COSV61862081; called by muse, mutect2, varscan2
- SIRPG | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 72/397 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99403711; called by muse, mutect2, varscan2
- SVIL | c.1625A>G p.K542R | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1349192380; called by muse, mutect2
- SYNE1 | c.19214C>T p.T6405I (on ENST00000367255 / NM_182961.4; = p.T6334I on NM_033071.3) | Missense Mutation (SNP) | VAF 82/527 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV55080795; called by muse, mutect2, varscan2
- TCF23 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767027596, COSV99940452; called by muse, mutect2, varscan2
- TRO | c.4169C>T p.P1390L | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.07); catalogued as rs769193458; called by muse, mutect2, varscan2
- TSHZ3 | c.1655C>A p.A552D | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53673264; called by muse, mutect2, varscan2
- WDR49 | c.896C>T p.T299M (on ENST00000308378 / NM_001366158.1; = p.T640M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200695837, COSV57704608; called by muse, mutect2
- ZNF768 | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV63323545; called by muse, mutect2, varscan2
- ZPLD1 | c.716C>T p.P239L (on ENST00000466937 / NM_001329788.1; = p.P255L on NM_175056.2) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.438); catalogued as COSV60355227; called by muse, mutect2
- ACE2 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ACVR2A | c.55+1G>T p.X19_splice | Splice Site (SNP) | VAF 65/410 reads (16%) | called by muse, mutect2, varscan2
- ADAM19 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3362C>G p.T1121S | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANTXR1 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 124/754 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- AP1AR | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 56/427 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APCDD1L | c.349T>A p.W117R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- C10orf71 | c.2240G>C p.W747S | Missense Mutation (SNP) | VAF 78/515 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CBLB | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CBLB | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDKAL1 | c.469-4_469-1delinsTTTT p.X157_splice | Splice Site (ONP) | VAF 8/88 reads (9%) | called by muse*, pindel
- CHD2 | c.1903_1906del p.D635Sfs*8 | Frame Shift Del (DEL) | VAF 72/472 reads (15%) | called by pindel, varscan2
- CHIC1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- EHBP1L1 | c.3898G>T p.D1300Y | Missense Mutation (SNP) | VAF 164/1099 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- EXOC3L1 | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FARS2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2, varscan2
- FAT4 | c.11869A>T p.S3957C | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- GTF2I | c.586+1_586+2del p.X196_splice | Splice Site (DEL) | VAF 36/340 reads (11%) | called by mutect2, varscan2
- HDAC6 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- HMCN1 | c.4277C>T p.A1426V | Missense Mutation (SNP) | VAF 89/594 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HUWE1 | c.12030G>T p.E4010D | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 110/1382 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KAT6B | c.846+4_846+7del p.X282_splice | Splice Site (DEL) | VAF 84/697 reads (12%) | called by mutect2, pindel, varscan2
- KREMEN1 | c.295G>T p.E99* (on ENST00000407188; = p.E101* on NM_032045.5) | Nonsense Mutation (SNP) | VAF 61/498 reads (12%) | called by muse, mutect2, varscan2
- MAOA | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 89/820 reads (11%) | called by muse, mutect2, varscan2
- MED12L | c.1031T>A p.V344E | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- NLRP3 | c.1368G>T p.Q456H | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDPR | c.1968G>T p.M656I | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PEG3 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.382); called by muse, mutect2
- PI16 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 54/514 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PODN | c.479A>T p.Y160F (on ENST00000395871; = p.Y112F on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, varscan2
- POTEC | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 177/950 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RNF213 | c.14333T>A p.L4778Q | Missense Mutation (SNP) | VAF 26/882 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SBK1 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SEMA5A | c.1457G>T p.R486M | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC29A2 | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 22/579 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.375); called by muse, mutect2
- STPG2 | c.1351A>T p.I451F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SUPT6H | c.4007A>T p.H1336L | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- TIAM1 | c.684A>T p.R228S | Missense Mutation (SNP) | VAF 94/512 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TIMP1 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM64B | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.164); called by muse, mutect2
- TRPA1 | c.2200A>G p.T734A | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- USP34 | c.6370A>G p.M2124V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- VENTX | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 37/192 reads (19%) | called by muse, mutect2, varscan2
- ZCCHC8 | c.405del p.F136Lfs*12 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- ZFHX2 | c.2266G>C p.D756H | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF676 | c.99G>T p.M33I (on ENST00000650058; = p.M1? on NM_001001411.3) | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZNF785 | c.131A>C p.E44A | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- ADAT2 | c.126T>G p.V42= | Silent (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- ALG6 | c.219A>T p.P73= | Silent (SNP) | VAF 48/242 reads (20%) | catalogued as rs187446493; called by muse, mutect2, varscan2
- ASZ1 | c.1353G>A p.L451= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV52912378; called by muse, mutect2, varscan2
- BNIP3 | c.528G>A p.K176= | Silent (SNP) | VAF 72/454 reads (16%) | called by muse, mutect2, varscan2
- C11orf49 | c.669C>T p.V223= | Silent (SNP) | VAF 74/341 reads (22%) | called by muse, mutect2, varscan2
- CFAP300 | c.456A>G p.S152= | Silent (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- FGD4 | c.666C>G p.V222= | Silent (SNP) | VAF 32/193 reads (17%) | called by muse, mutect2, varscan2
- FOXN4 | c.123G>T p.G41= | Silent (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- FRY | c.6411C>T p.H2137= | Silent (SNP) | VAF 80/459 reads (17%) | catalogued as rs559252996; called by muse, mutect2, varscan2
- GAPVD1 | c.2490A>T p.P830= (on ENST00000394104; = p.P857= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/295 reads (17%) | called by muse, mutect2, varscan2
- LANCL1 | c.636A>G p.E212= | Silent (SNP) | VAF 37/275 reads (13%) | called by muse, mutect2, varscan2
- MUC17 | c.8688C>T p.T2896= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs1356288194; called by muse, mutect2, varscan2
- MYH1 | c.1560G>T p.L520= | Silent (SNP) | VAF 91/519 reads (18%) | catalogued as rs772505014, COSV56846089; called by muse, mutect2, varscan2
- NOX1 | c.357C>T p.H119= | Silent (SNP) | VAF 41/264 reads (16%) | called by muse, mutect2, varscan2
- PRR12 | c.534G>A p.S178= (on ENST00000615927; = p.S999= on NM_020719.3) | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- PRR5 | c.894G>A p.P298= (on ENST00000336985 / NM_181333.4; = p.P289= on NM_015366.4) | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs201222885; called by muse, mutect2, varscan2
- RTL3 | c.411G>A p.E137= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs747453158; called by muse, mutect2, varscan2
- RUBCNL | c.1635A>G p.A545= | Silent (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- RYR2 | c.8508C>T p.D2836= | Silent (SNP) | VAF 60/530 reads (11%) | catalogued as rs757197730, COSV100769884; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM200A | c.654C>T p.S218= | Silent (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- TPO | c.1416C>A p.G472= | Silent (SNP) | VAF 98/603 reads (16%) | catalogued as COSV100221770; called by muse, mutect2, varscan2
- VCAN | c.7440T>C p.D2480= | Silent (SNP) | VAF 121/589 reads (21%) | catalogued as rs1413827352; called by muse, mutect2, varscan2
- AC023469.1 | n.203G>A | RNA (SNP) | VAF 66/333 reads (20%) | called by muse, mutect2, varscan2
- AC079154.1 | n.821T>A | RNA (SNP) | VAF 10/62 reads (16%) | called by muse, varscan2
- C17orf99 | c.640+252A>T | Intron (SNP) | VAF 37/290 reads (13%) | called by muse, mutect2, varscan2
- GBE1 | c.*36G>C | 3'UTR (SNP) | VAF 46/273 reads (17%) | called by muse, mutect2, varscan2
- GRB10 | c.846+37T>C | Intron (SNP) | VAF 136/635 reads (21%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3255del | Intron (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel
- MAGEA5 | n.316del | RNA (DEL) | VAF 45/376 reads (12%) | called by mutect2, pindel, varscan2
- MAMLD1 | c.*595G>T | 3'UTR (SNP) | VAF 32/202 reads (16%) | called by muse, mutect2, varscan2
- MIR1202 | n.57G>A | RNA (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- PKD1L2 | c.2778+160del | Intron (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- SLC12A6 | c.271+17848_271+17851del | Intron (DEL) | VAF 117/807 reads (14%) | called by mutect2, pindel, varscan2
- SLC35F5 | c.-10C>G | 5'UTR (SNP) | VAF 40/313 reads (13%) | called by muse, mutect2, varscan2
- SYPL1 | c.645+289C>T | Intron (SNP) | VAF 20/130 reads (15%) | catalogued as rs758064271; called by muse, mutect2, varscan2
- TNFRSF10B | c.*859_*860insACTG | 3'UTR (INS) | VAF 116/481 reads (24%) | called by mutect2, pindel, varscan2
- ZNF729 | c.-76G>A | 5'UTR (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
